Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4759, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4759-01A (Primary Tumor).

[page 1 of 2]
.....

Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

1: SP: Left renal tumor [REDACTED]

2: SP: Deep margin #2 [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, LEFT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL (CONVENTIONAL) TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 3.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- THE SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 2) KIDNEY, DEEP MARGIN #2; EXCISION:
- BENIGN RENAL PARENCHYMA.
- [REDACTED]
- [REDACTED]

1) The specimen is received fresh for frozen section, labeled "Left renal tumor". It consists of a partial nephrectomy specimen measuring 5.5 x 4.5 x 3.5 cm. The kidney measures 4.5 x 4.0 x 3.0 cm. Attached perirenal fat measures 4.5 x 4.0 x 2.0 cm. The surgical resection margin is inked black and the fat is inked green. The fat is detached from the renal cortical surface. On serial sectioning, a well-circumscribed, focally encapsulated, round, bright yellow mass is seen, measuring 3.0 x 2.5 x 2.5 cm. Focal hemorrhages and a central tan-white area are also seen. Tumor is located 0.1 cm from the resection margin. Representative sections are submitted.

Summary of Sections:

FSC - Frozen section control

T - Tumor with inked resection margin and cortical surface

F - Fat

[REDACTED]

2) The specimen is received fresh for frozen section, labeled "Deep margin #2". It consists of a 1.6 x 1.4 x 0.6 cm portion of brown soft tissue with minimal fat. The entire specimen is submitted for frozen section.

[page 2 of 2]
Summary of Sections:
FSC - Frozen section control

Summary of Sections:

Part 1: SP: Left renal tumor [REDACTED]

Block	Sect. Site	PCs
1	f	1
1	fsc	1
4	t	4

Part 2: SP: Deep margin #2 ([REDACTED])

Block	Sect. Site	PCs
1	fsc	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, CLEAR CELL TYPE. MARGIN NEGATIVE. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- [REDACTED]

Source: NCI Genomic Data Commons file d6430945-bd5f-424c-b019-47f21ffdbcda (TCGA-BP-4759.57EEF023-E30D-4812-A959-40A8DDC65DA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).